Somatic mutation profile of tumor specimen TCGA-BJ-A0ZF-01A (aliquot TCGA-BJ-A0ZF-01A-11D-A10S-08) from TCGA case TCGA-BJ-A0ZF, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Follicular carcinoma, minimally invasive; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 54.7 years (19,978 days).
Specimen TCGA-BJ-A0ZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e03446d-961e-4e53-b7f6-feda7f6d510d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0ZF-10A (Blood Derived Normal), aliquot TCGA-BJ-A0ZF-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/612cf3bd-f0d7-424c-aa3c-5bb9eaddd7b5

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP32 | c.4850T>G p.L1617R (on ENST00000310343 / NM_001378025.1; = p.L1268R on NM_014715.4) | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV100088624; called by muse, mutect2, varscan2
- CORO7 | c.2268C>G p.F756L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as rs372039186, COSV99227982; called by muse, mutect2, varscan2
- CSMD2 | c.5546C>A p.S1849* | Nonsense Mutation (SNP) | VAF 57/148 reads (39%) | catalogued as COSV53899956; called by muse, mutect2, varscan2
- DIO1 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs775385417, COSV99301089; called by muse, mutect2, varscan2
- DNAH1 | c.3607A>G p.M1203V | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs371532292; called by muse, mutect2, varscan2
- HLA-DPB1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1332954676, COSV101331040; called by muse, mutect2
- KMT5C | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99726273; called by muse, mutect2
- LRRC8A | c.1081A>C p.S361R | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV99396799; called by muse, mutect2, varscan2
- MAP3K8 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1196207926, COSV99552261; called by muse, mutect2, varscan2
- NDC80 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99859858; called by muse, mutect2, varscan2
- NLRX1 | c.2608C>T p.L870F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99424656; called by muse, varscan2
- OR4C6 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs772626217, COSV58604155; called by muse, mutect2, varscan2
- PPARA | c.958A>G p.M320V | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs781580066, COSV99415766; called by muse, mutect2
- PTPRD | c.3580G>A p.A1194T | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1427192894, COSV61944849; called by muse, mutect2
- RUSF1 | c.905G>C p.R302T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV100393336; called by muse, mutect2, varscan2
- UGT2A1 | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99684710; called by muse, varscan2
- ZFYVE16 | c.4025-1G>T p.X1342_splice | Splice Site (SNP) | VAF 47/142 reads (33%) | catalogued as COSV100566374; called by muse, mutect2, varscan2
- ZNF106 | c.5420T>G p.L1807R | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99782965; called by muse, mutect2
- TOGARAM2 | c.2915C>T p.A972V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2
- CDHR5 | c.75C>A p.A25= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99449307; called by muse, mutect2, varscan2
- FAT4 | c.6783A>G p.L2261= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as COSV100629510; called by muse, mutect2
- GOSR1 | c.276C>T p.T92= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as rs769117010, COSV99853756; called by muse, mutect2, varscan2
